Somatic mutation profile of tumor specimen TCGA-RT-A6YA-01A (aliquot TCGA-RT-A6YA-01A-12D-A35D-08) from TCGA case TCGA-RT-A6YA, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 71.4 years (26,095 days).
Specimen TCGA-RT-A6YA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5631e078-83e9-4605-babc-483c55d24c74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RT-A6YA-10B (Blood Derived Normal), aliquot TCGA-RT-A6YA-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a599f0a-cdc7-4d4c-9415-c60360f8b15a

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGAT2 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs752069694; called by muse, mutect2, varscan2
- IRF9 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs569115226; called by muse, mutect2, varscan2
- NF1 | c.2990G>C p.R997T | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1555614462, CM143354, CS1311519, COSV62202923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.5459G>A p.R1820H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.695); catalogued as rs750141316; called by muse, mutect2, varscan2
- SEC14L5 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs781428450; called by muse, mutect2, varscan2
- SLC12A8 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs769225257, COSV58866249; called by muse, mutect2, varscan2
- ARID2 | c.4201A>C p.I1401L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- COLGALT2 | c.1150A>C p.S384R | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FBXL20 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FGD6 | c.1041C>G p.S347R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FOXA2 | c.549C>G p.S183R (on ENST00000377115 / NM_153675.3; = p.S189R on NM_021784.5) | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- KBTBD2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCT | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO5C | c.4940C>T p.T1647I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRD9 | c.1994T>C p.V665A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2
- RC3H1 | c.1866C>T p.S622= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- TAB3 | c.51A>G p.R17= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- FOXM1 | c.1267-1664T>C | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs1202820848; called by muse, mutect2
